Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A1QE, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A1QE-01A (Primary Tumor).

[page 1 of 2]
Head And Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

y/o female with right thyroid nodule which shows outside path consistent with papillary cancer.

Specimens Submitted:

1: SP: Right thyroid lobe (

DIAGNOSIS:

100-0-3 Carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C23.9 3/16/11

- 1) THYROID, RIGHT; PARTIAL THYROIDECTOMY:
- PAPILLARY CARCINOMA, CLASSICAL TYPE, PREDOMINANTLY WELL-DIFFERENTIATED WIT FOCAL AREAS OF TALL-CELL CHANGES (SEE NOTE).
- MITOTIC ACTIVITY IS NIL.
- NO TUMOR NECROSIS IS IDENTIFIED.
- THE TUMOR INVOLVES THE RIGHT LOBE.
- THE TUMOR GREATEST DIAMETER IS 1.5 CM.
- NO EVIDENCE OF BLOOD VESSEL INVASION IS IDENTIFIED.
- THERE IS FOCAL EXTRATHYROID EXTENSION INTO SOFT TISSUE.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- NO EVIDENCE OF TUMOR MULTICENTRICITY IS IDENTIFIED.
- THE NON-NEOPLASTIC THYROID SHOWS NO ABNORMALITIES.
- NO PARATHYROID GLANDS ARE IDENTIFIED.
- FRAGMENT OF ATROPHIC THYMUS ADJACENT TO THYROID CAPSULE.

NOTE: REPRESENTATIVE SLIDES WERE REVIEWED IN CONSULTATION WITH

WHO AGREES WITH THIS

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "Right Thyroid Lobe". It consists of a partial thyroidectomy specimen, received previously bisected, measuring 4 x 2 x 1.5 cm and weighing 9 grams. The surface is inked. The specimen is serially sectioned. The cut surface reveals a 1.5 x 1.5 x 1 cm, fairly well-circumscribed, tan, indurated lesion. The rest of the thyroid parenchyma is unremarkable. The entire thyroid and nodule are submitted. Sections of the tumor and the thyroid are submitted for TPS.

Summary of Sections:

N - nodule
T - thyroid

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Summary of Sections:

Part 1: SP: Right thyroid lobe (sr)

Block	Sect. Site	PCs
6	N	6
4	T	4

Source: NCI Genomic Data Commons file 314ef293-071d-475f-94cb-30aa57499b57 (TCGA-DJ-A1QE.B7953E61-5047-4648-8A15-DE47510090BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).